Gene-level copy-number profile of tumor specimen TCGA-24-1845-01A from TCGA case TCGA-24-1845, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.7 years (15,599 days).
Specimen TCGA-24-1845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8f021990-860f-4883-ba30-e2d7f1956280.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1845-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e819d944-4a76-4716-8ca9-7ea568a281ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 1,995; copy number 2: 14,273; copy number 3: 15,974; copy number 4: 12,597; copy number 5: 7,391; copy number 6: 5,795; copy number 7: 1,416; copy number 8: 191; copy number 9: 113; copy number 10: 33; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1845-01A-01D-0577-01): tumor purity 0.86, ploidy 3.44, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,193,100–190,092,279, 29 genes: AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,549 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,122,022–36,305,357, 35 genes, copy number 5 (within-gene range 3–5): EFCAB14P1, AL590434.1, SFPQ, Y_RNA, ZMYM4, RN7SL503P, SNORA62, RPL5P4, ZMYM4-AS1, Metazoa_SRP, KIAA0319L, AC004865.1, NCDN, TFAP2E-AS1, TFAP2E, PSMB2, C1orf216, CLSPN, AL354864.1, AGO4, AGO1, CFAP97P1, AL139286.2, AL139286.1, AGO3, AL138787.2, AL138787.1, TEKT2, ADPRS, COL8A2, TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4.
- chr1:39,081,316–248,919,946, 4,218 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–13,331,683, 219 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:15,690,782–15,744,339, 1 gene, copy number 5 (within-gene range 4–5): LINC01804.
- chr2:18,403,967–41,157,555, 410 genes, copy number 5 (broad region; genes not listed).
- chr2:136,329,441–192,776,899, 726 genes, copy number 6–7 (broad region; genes not listed).
- chr3:135,965,728–179,465,328, 650 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr6:167,607–53,665,756, 1,469 genes, copy number 6–9 (broad region; genes not listed).
- chr7:29,122,340–29,514,667, 2 genes, copy number 5 (within-gene range 4–5): AC004593.2, CHN2.
- chr7:29,514,224–36,841,373, 144 genes, copy number 5 (broad region; genes not listed).
- chr7:36,919,357–36,919,432, 1 gene, copy number 5: MIR1200.
- chr7:99,173,574–134,066,589, 661 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr7:134,284,500–158,587,823, 586 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:41,929,479–43,674,591, 57 genes, copy number 5: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:124,973,295–145,066,685, 371 genes, copy number 5 (broad region; genes not listed).
- chr9:16,409,503–17,503,923, 12 genes, copy number 5 (within-gene range 4–5): BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr11:72,002,864–72,080,693, 1 gene, copy number 5 (within-gene range 4–5): NUMA1.
- chr11:72,047,873–135,075,908, 1,313 genes, copy number 5–10 (broad region; genes not listed).
- chr12:5,948,877–7,567,382, 93 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:26,120,030–27,502,185, 29 genes, copy number 6 (within-gene range 4–6): BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2.
- chr12:65,278,643–65,491,430, 1 gene, copy number 7 (within-gene range 4–7): MSRB3.
- chr12:65,418,731–68,971,570, 79 genes, copy number 7 (broad region; genes not listed).
- chr12:105,235,290–105,396,097, 1 gene, copy number 5 (within-gene range 3–5): C12orf75.
- chr12:105,304,867–133,214,832, 745 genes, copy number 5–6 (broad region; genes not listed).
- chr17:69,414,697–81,117,432, 346 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:60,519,841–80,247,514, 276 genes, copy number 5 (broad region; genes not listed).
- chr19:13,069,792–41,930,150, 1,124 genes, copy number 5–6 (broad region; genes not listed).
- chr20:47,501,887–64,313,132, 404 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:15,290,718–17,266,733, 88 genes, copy number 6 (broad region; genes not listed).
- chr22:19,714,503–24,008,258, 332 genes, copy number 5–9 (broad region; genes not listed).
- chr22:27,978,014–28,679,865, 1 gene, copy number 6 (within-gene range 3–6): TTC28.
- chr22:28,303,754–30,177,075, 57 genes, copy number 6 (within-gene range 2–6): Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB, CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1, GAS2L1, RASL10A, AC002059.1, AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51.
- chr22:37,166,757–39,055,972, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
